Somatic mutation profile of tumor specimen TCGA-2E-A9G8-01A (aliquot TCGA-2E-A9G8-01A-11D-A403-09) from TCGA case TCGA-2E-A9G8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Fundus uteri; FIGO stage: Stage III; Tumor grade: G2.
Specimen TCGA-2E-A9G8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47fd30d5-3128-4974-a70d-dad7fe85ee7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2E-A9G8-10A (Blood Derived Normal), aliquot TCGA-2E-A9G8-10A-01D-A403-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89803c71-db84-4c6f-a02c-2fafe95209a6

The open-access MAF lists 67 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 37, Silent 14, Nonsense Mutation 5, In Frame Del 5, Frame Shift Del 4, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 16/43 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.856_861del p.E286_E287del | In Frame Del (DEL) | VAF 10/18 reads (56%) | hotspot (GDC flag); called by mutect2, varscan2
- AGXT2 | c.1264C>T p.R422W | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs553649751, COSV99183765; called by muse, mutect2, varscan2
- BCL11A | c.2063C>T p.T688M (on ENST00000335712 / NM_001365609.1; = p.T722M on NM_018014.4) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as COSV59624970; called by muse, mutect2
- CAB39L | c.83T>A p.L28* | Nonsense Mutation (SNP) | VAF 49/69 reads (71%) | catalogued as COSV100759573; called by muse, mutect2, varscan2
- CDC37 | c.136_138del p.E46del | In Frame Del (DEL) | VAF 10/82 reads (12%) | catalogued as rs1568354981; called by mutect2, pindel, varscan2
- CFAP65 | c.956C>G p.A319G | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV99838351; called by muse, mutect2, varscan2
- CHD1 | c.4733_4735del p.S1578del | In Frame Del (DEL) | VAF 42/110 reads (38%) | catalogued as rs772633798; called by pindel, varscan2
- CHD4 | c.3346G>C p.G1116R (on ENST00000357008 / NM_001363606.2; = p.G1129R on NM_001273.5) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100538156; called by muse, mutect2, varscan2
- CYP4B1 | c.1282_1283del p.L428Afs*5 | Frame Shift Del (DEL) | VAF 10/32 reads (31%) | catalogued as rs756135384; called by pindel, varscan2
- ELOB | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 61/112 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.164); catalogued as rs533452752, COSV99241515; called by muse, mutect2, varscan2
- EPHA2 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781593323, COSV100626147, COSV64452014; called by muse, mutect2, varscan2
- F8 | c.4937C>A p.A1646E | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.06); PolyPhen benign (0.084); catalogued as COSV64279385; called by muse, mutect2, varscan2
- F9 | c.1163T>A p.F388Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as CM1314903, COSV99496610; called by muse, mutect2
- FASTK | c.1411C>G p.R471G | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV99879799; called by muse, mutect2, varscan2
- GAMT | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs761599682, COSV99282813; called by muse, mutect2, varscan2
- GJA8 | c.563G>A p.C188Y | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99569435; called by muse, mutect2, varscan2
- GLS | c.1375T>G p.L459V | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.744); catalogued as COSV100290164; called by muse, mutect2, varscan2
- GLTP | c.536A>C p.K179T | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.092); catalogued as COSV100570316; called by muse, mutect2, varscan2
- IL23R | c.794G>A p.W265* | Nonsense Mutation (SNP) | VAF 43/94 reads (46%) | catalogued as COSV100724771; called by muse, mutect2, varscan2
- LAMB1 | c.1925G>C p.R642P | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.55); PolyPhen benign (0.037); catalogued as COSV55969391, COSV99740944; called by muse, mutect2, varscan2
- LRRK2 | c.5164G>C p.G1722R | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV100110361, COSV100110882; called by muse, mutect2, varscan2
- LYPD4 | c.538+1G>C p.X180_splice | Splice Site (SNP) | VAF 11/14 reads (79%) | catalogued as COSV100419422; called by muse, mutect2, varscan2
- MAP7D2 | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs1362231247, COSV101107376; called by muse, mutect2, varscan2
- MECR | c.920T>A p.L307H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99747125; called by muse, mutect2, varscan2
- MED17 | c.1925T>G p.L642R | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99316044; called by muse, mutect2, varscan2
- MYO18A | c.4642G>A p.E1548K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100572351; called by muse, mutect2, varscan2
- NBEAL1 | c.7837G>C p.D2613H | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.088); catalogued as COSV101355525; called by muse, mutect2, varscan2
- NOTCH3 | c.129C>A p.C43* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99657491; called by muse, mutect2
- NT5DC1 | c.935G>A p.G312D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100126818; called by muse, mutect2
- OGT | c.2914A>C p.N972H | Missense Mutation (SNP) | VAF 60/162 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV101035436; called by muse, mutect2, varscan2
- OR4A5 | c.617T>C p.V206A | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); catalogued as rs747110828, COSV100157126; called by muse, mutect2, varscan2
- SELE | c.637G>C p.G213R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100324827; called by muse, mutect2, varscan2
- SLITRK2 | c.917A>C p.K306T | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as COSV100157831; called by muse, mutect2, varscan2
- SRGAP3 | c.2758G>A p.A920T | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen probably damaging (0.959); catalogued as rs535473258, COSV64531393, COSV64535889; called by muse, mutect2, varscan2
- SYNM | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555485804, COSV100152780; called by muse, mutect2, varscan2
- TG | c.7129C>A p.P2377T | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV55091210, COSV99601184; called by muse, mutect2, varscan2
- TP63 | c.382T>G p.S128A | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as COSV99287160; called by muse, mutect2, varscan2
- TRIP4 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.024); catalogued as COSV56033306; called by muse, mutect2, varscan2
- TTC27 | c.223G>C p.V75L | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100513133; called by muse, mutect2, varscan2
- UNC13A | c.2263C>T p.Q755* | Nonsense Mutation (SNP) | VAF 12/106 reads (11%) | catalogued as COSV99408512; called by muse, mutect2
- USP24 | c.2723T>C p.V908A | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.9); catalogued as COSV99599944; called by muse, mutect2, varscan2
- WDR36 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV101540807; called by muse, mutect2, varscan2
- YAP1 | c.371G>C p.R124P | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV56773530, COSV56774616; called by muse, mutect2, varscan2
- ZBTB14 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.18); catalogued as COSV100813464; called by muse, mutect2, varscan2
- ZNF449 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 27/57 reads (47%) | catalogued as COSV100202996; called by muse, mutect2, varscan2
- ZNF839 | c.1345C>T p.R449W (on ENST00000558850 / NM_001267827.1; = p.R565W on NM_018335.5) | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs535523717, COSV51757900, COSV99216274; called by muse, mutect2, varscan2
- L1CAM | c.402_414del p.A135Qfs*5 | Frame Shift Del (DEL) | VAF 18/47 reads (38%) | called by mutect2, pindel, varscan2
- MACF1 | c.20261_20262del p.S6754Cfs*8 (on ENST00000372915; = p.S4799Cfs*8 on NM_012090.5) | Frame Shift Del (DEL) | VAF 24/67 reads (36%) | called by pindel, varscan2
- PARD3 | c.2554dup p.S852Kfs*8 | Frame Shift Ins (INS) | VAF 40/122 reads (33%) | called by mutect2, pindel, varscan2
- STAT2 | c.1775_1777del p.K592del | In Frame Del (DEL) | VAF 7/34 reads (21%) | called by pindel, varscan2
- TSHR | c.559_561del p.N187del | In Frame Del (DEL) | VAF 5/16 reads (31%) | called by mutect2, varscan2
- ZNF436 | c.603_604del p.S202Ffs*23 | Frame Shift Del (DEL) | VAF 19/76 reads (25%) | called by mutect2, pindel, varscan2
- BTC | c.510A>G p.E170= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV101201536; called by muse, mutect2, varscan2
- C10orf71 | c.1515C>T p.D505= | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as rs770842902, COSV60514817; called by muse, mutect2, varscan2
- GOLGA3 | c.69C>A p.L23= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99207549; called by muse, mutect2, varscan2
- HNF4A | c.801C>G p.R267= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100291436; called by muse, mutect2, varscan2
- IGKV1-12 | c.141G>A p.A47= | Silent (SNP) | VAF 26/108 reads (24%) | catalogued as rs772096999; called by muse, mutect2
- KCNK2 | c.129G>A p.V43= (on ENST00000444842 / NM_001017425.3; = p.V28= on NM_014217.4) | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV101222188; called by muse, mutect2, varscan2
- LHFPL1 | c.490C>A p.R164= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV100914477; called by muse, mutect2, varscan2
- NKX3-2 | c.786G>A p.K262= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV101219906; called by muse, mutect2, varscan2
- OR4C15 | c.639T>A p.I213= (on ENST00000314644; = p.I159= on NM_001001920.2) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100115730; called by muse, mutect2, varscan2
- PRLHR | c.168G>C p.V56= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99492815; called by muse, mutect2, varscan2
- PTPRR | c.63C>T p.C21= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99317723; called by muse, mutect2, varscan2
- SCML2 | c.1983T>C p.D661= | Silent (SNP) | VAF 31/78 reads (40%) | catalogued as COSV99319057; called by muse, mutect2, varscan2
- TTLL2 | c.1578C>A p.S526= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as COSV99514757; called by muse, mutect2, varscan2
- XCR1 | c.777C>T p.C259= | Silent (SNP) | VAF 13/17 reads (76%) | catalogued as rs573724659, COSV58569890; called by muse, mutect2, varscan2
